Somatic mutation profile of tumor specimen TCGA-KF-A41W-01A (aliquot TCGA-KF-A41W-01A-11D-A24N-09) from TCGA case TCGA-KF-A41W, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Uterus, NOS; Age at diagnosis: 71.1 years (25,969 days).
Specimen TCGA-KF-A41W-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b3f7bf38-7f92-42cc-8919-86cde2322292.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KF-A41W-10A (Blood Derived Normal), aliquot TCGA-KF-A41W-10A-01D-A24N-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1fb074e9-2858-47c0-a0f9-345a585260f5

The open-access MAF lists 51 somatic variants for this specimen: 36 protein-altering or splice-affecting, 15 silent.
By variant classification: Missense Mutation 28, Silent 15, Nonsense Mutation 3, Splice Region 2, Splice Site 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.583A>T p.I195F | Missense Mutation (SNP) | VAF 23/54 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs942158624, COSV52677568, COSV52809310, COSV53233300; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- BCORL1 | c.629C>T p.S210L | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.043); catalogued as rs267606346, COSV54393478, COSV99498287; called by muse, mutect2, varscan2
- BRINP3 | c.434A>T p.E145V | Missense Mutation (SNP) | VAF 27/50 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100819374; called by muse, mutect2, varscan2
- C14orf177 | n.619G>T | Splice Region (SNP) | VAF 61/87 reads (70%) | catalogued as COSV100362738; called by muse, mutect2, varscan2
- CCDC158 | c.1810A>T p.M604L | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101187359; called by muse, mutect2, varscan2
- CELSR3 | c.2944C>A p.Q982K | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV99374824; called by muse, mutect2, varscan2
- CIB3 | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs761331076, COSV54165989; called by muse, mutect2, varscan2
- DOCK8 | c.529-1G>A p.X177_splice | Splice Site (SNP) | VAF 14/65 reads (22%) | catalogued as COSV101210346; called by muse, mutect2, varscan2
- DPYSL5 | c.20G>T p.S7I | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.318); catalogued as COSV99982747; called by muse, mutect2, varscan2
- DROSHA | c.3224G>A p.R1075H | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.65); PolyPhen benign (0.018); catalogued as rs1186040397, COSV100757688; called by muse, mutect2, varscan2
- EPRS1 | c.1274G>T p.R425L | Missense Mutation (SNP) | VAF 11/146 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100859484, COSV65099596; called by muse, mutect2
- FAM86B1 | c.455T>A p.F152Y | Missense Mutation (SNP) | VAF 94/574 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100392464; called by muse, varscan2
- FGA | c.1340A>T p.E447V | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as COSV100120689; called by muse, mutect2, varscan2
- FNBP1L | c.405T>C p.N135= | Splice Region (SNP) | VAF 33/92 reads (36%) | catalogued as rs745858363, COSV99554970; called by muse, mutect2, varscan2
- FUT1 | c.790G>A p.G264S | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs924183634, COSV59568195; called by muse, mutect2, varscan2
- GPC5 | c.788G>A p.G263D | Missense Mutation (SNP) | VAF 24/39 reads (62%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.816); catalogued as rs373404359; called by muse, mutect2, varscan2
- GRM1 | c.965A>G p.D322G | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as COSV99268676; called by muse, mutect2, varscan2
- KRCC1 | c.360del p.F120Lfs*13 | Frame Shift Del (DEL) | VAF 13/99 reads (13%) | catalogued as COSV61251644; called by mutect2, pindel, varscan2
- LNPEP | c.2628C>G p.F876L | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.056); catalogued as COSV99183603; called by muse, mutect2, varscan2
- MMP26 | c.595+2T>C p.X199_splice | Splice Site (SNP) | VAF 24/134 reads (18%) | catalogued as COSV56171413; called by muse, mutect2, varscan2
- MSLN | c.1327G>A p.A443T (on ENST00000382862 / NM_013404.4; = p.A435T on NM_005823.6) | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.46); PolyPhen benign (0.018); catalogued as rs749126758, COSV53505344; called by muse, mutect2, varscan2
- MTUS1 | c.320C>A p.A107E | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.563); catalogued as COSV100029964; called by muse, mutect2, varscan2
- OR4N5 | c.699G>T p.K233N | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100374217, COSV61321055; called by muse, mutect2, varscan2
- OR51G1 | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); catalogued as rs568109165, COSV100429403; called by muse, mutect2, varscan2
- PDCL | c.215T>G p.L72W | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99414217; called by muse, mutect2
- PIK3C2G | c.3778A>T p.N1260Y (on ENST00000676171; = p.N1219Y on NM_004570.5) | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV99853730; called by muse, mutect2, varscan2
- SKI | c.1229G>C p.S410T | Missense Mutation (SNP) | VAF 72/178 reads (40%) | SIFT tolerated (0.89); PolyPhen possibly damaging (0.824); catalogued as COSV101049587; called by muse, mutect2, varscan2
- SKI | c.1627G>C p.E543Q | Missense Mutation (SNP) | VAF 61/170 reads (36%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.815); catalogued as COSV101049589; called by muse, mutect2, varscan2
- SMARCA4 | c.41C>T p.P14L | Missense Mutation (SNP) | VAF 41/83 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV100759090; called by muse, mutect2, varscan2
- STK32C | c.301A>T p.K101* | Nonsense Mutation (SNP) | VAF 46/76 reads (61%) | catalogued as COSV100063376; called by muse, mutect2, varscan2
- SYCP1 | c.2104C>T p.R702* | Nonsense Mutation (SNP) | VAF 9/51 reads (18%) | catalogued as COSV101051178; called by muse, mutect2, varscan2
- TEX15 | c.4792G>T p.V1598L (on ENST00000256246; = p.V1981L on NM_001350162.2) | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV99822033; called by muse, mutect2, varscan2
- TFR2 | c.1289G>C p.G430A | Missense Mutation (SNP) | VAF 52/73 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754922209, COSV99774711; called by muse, mutect2, varscan2
- TRPM4 | c.3329G>A p.R1110Q | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.537); catalogued as rs1417439106, COSV99420814; called by muse, mutect2, varscan2
- VPS35 | c.1842T>G p.Y614* | Nonsense Mutation (SNP) | VAF 15/44 reads (34%) | catalogued as COSV100140780; called by muse, mutect2, varscan2
- ZNF584 | c.766G>A p.A256T | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT tolerated (0.27); PolyPhen benign (0.284); catalogued as COSV59722069; called by muse, mutect2, varscan2
- ANKRD35 | c.1113G>A p.Q371= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as COSV100841841; called by muse, mutect2, varscan2
- C2orf50 | c.456G>A p.K152= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as COSV67510584, COSV67510945; called by muse, varscan2
- CATSPER1 | c.1653G>T p.L551= | Silent (SNP) | VAF 26/57 reads (46%) | catalogued as COSV100376217; called by muse, mutect2, varscan2
- CDH9 | c.135T>G p.G45= | Silent (SNP) | VAF 38/63 reads (60%) | catalogued as COSV99151624; called by muse, mutect2, varscan2
- CETP | c.1371C>T p.L457= | Silent (SNP) | VAF 20/31 reads (65%) | catalogued as COSV99570327; called by muse, mutect2, varscan2
- CYP1B1 | c.216C>A p.L72= | Silent (SNP) | VAF 3/33 reads (9%) | called by muse, mutect2
- DSG2 | c.2244A>C p.A748= | Silent (SNP) | VAF 21/47 reads (45%) | catalogued as COSV99853522; called by muse, mutect2, varscan2
- LRFN2 | c.2290T>C p.L764= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV100599902; called by muse, mutect2
- MMP24 | c.831C>T p.F277= | Silent (SNP) | VAF 45/108 reads (42%) | catalogued as COSV99864104; called by muse, mutect2, varscan2
- NUGGC | c.120C>T p.P40= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as COSV100429743; called by muse, mutect2, varscan2
- SLC26A8 | c.1116C>T p.L372= | Silent (SNP) | VAF 26/62 reads (42%) | catalogued as COSV100839600; called by muse, mutect2, varscan2
- SPTA1 | c.6741G>A p.Q2247= | Silent (SNP) | VAF 29/100 reads (29%) | catalogued as COSV100935503; called by muse, mutect2, varscan2
- USP50 | c.390A>C p.P130= (on ENST00000616326; = p.P121= on NM_203494.5) | Silent (SNP) | VAF 23/38 reads (61%) | catalogued as COSV101597735; called by muse, mutect2, varscan2
- ZC3H12B | c.1650T>A p.G550= | Silent (SNP) | VAF 21/43 reads (49%) | catalogued as COSV100161992; called by muse, mutect2, varscan2
- ZNF596 | c.1278A>G p.K426= | Silent (SNP) | VAF 5/57 reads (9%) | catalogued as COSV100261786; called by muse, mutect2, varscan2
